Gene-level copy-number profile of tumor specimen HTMCP-03-06-02322-01A from CGCI case HTMCP-03-06-02322, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02322-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da597460-ebd3-46d3-8486-a0a1ceaea1ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02322-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/12e394de-c8c4-4310-830e-4c88dbbce637

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 10,018; copy number 2: 34,137; copy number 3: 11,186; copy number 4: 2,735; copy number 5: 305; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 317 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes, copy number 5: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr3:145,523,538–154,121,347, 149 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:188,941,715–189,325,304, 4 genes, copy number 5: TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr5:12,297,399–19,234,487, 110 genes, copy number 5 (broad region; genes not listed).
- chr8:38,223,957–38,853,028, 19 genes, copy number 5–6 (within-gene range 2–6): AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1.
- chr12:24,993,424–25,648,579, 18 genes, copy number 5: C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr12:63,779,842–64,162,217, 10 genes, copy number 5–6 (within-gene range 3–6): RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3.
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.

Autosomal genes at a single copy (total copy number 1): 10,018. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
